Gene-level copy-number profile of tumor specimen TCGA-05-4389-01A from TCGA case TCGA-05-4389, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 70.3 years (25,660 days).
Specimen TCGA-05-4389-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.0a89d832-126a-46b9-b981-229eb0309986.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-05-4389-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0a50c9ec-24b4-4caf-ad63-f274f3d524b6

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 184; copy number 2: 15,990; copy number 3: 11,816; copy number 4: 9,896; copy number 5: 16,892; copy number 6: 2,994; copy number 7: 1,055; copy number 8: 685; copy number 9: 145; copy number 12: 74; copy number 14: 83.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-05-4389-01A-01D-1204-01): tumor purity 0.48, ploidy 3.23, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 157 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:40,530,590–50,796,692, 157 genes, copy number 12–14 (within-gene range 4–14) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 184. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
